Somatic mutation profile of tumor specimen C3L-09379-02 (aliquot CPT0503170006) from CPTAC case C3L-09379, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.2 years (23,463 days).
Specimen C3L-09379-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7ebedde-9017-4d67-8db9-3288f01a217b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09379-31 (Blood Derived Normal), aliquot CPT0503310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51ed72ff-f5c3-4b48-b0b4-04113f9cddd5

The open-access MAF lists 163 somatic variants for this specimen: 120 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 37, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 2, Intron 2, RNA 1, 5'Flank 1, 5'UTR 1, Splice Region 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG2A | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 27/472 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs936744569; called by muse, mutect2
- AUTS2 | c.3179G>A p.R1060H | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1196040328; called by muse, mutect2
- CABLES2 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 38/552 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs766780171, COSV99653111; called by muse, mutect2
- CACNA1A | c.7334C>T p.P2445L | Missense Mutation (SNP) | VAF 44/807 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.112); catalogued as rs1235870142; called by muse, mutect2
- COL7A1 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780113498, COSV60392078; called by muse, mutect2
- COP1 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 20/286 reads (7%) | catalogued as COSV58164477; called by muse, mutect2
- CREB3L2 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 34/404 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV57792037; called by muse, mutect2
- DCC | c.1403G>T p.R468I | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV100503040; called by muse, mutect2
- DRAXIN | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV99610975; called by muse, mutect2
- EVPLL | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 30/528 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as rs779054522; called by muse, mutect2
- FBN3 | c.7187C>T p.P2396L | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs372328082, COSV54464740; called by muse, mutect2
- FBXO38 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1392489697; called by muse, mutect2
- GPR155 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 27/310 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs745614550; called by muse, mutect2
- GPR26 | c.921G>T p.E307D | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99501129; called by muse, mutect2
- GRM1 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51136069; called by muse, mutect2
- GTPBP3 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 36/595 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1224174744; called by muse, mutect2
- HDAC7 | c.1907A>G p.N636S (on ENST00000427332; = p.N675S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/340 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as rs192475049; called by muse, mutect2
- HLA-A | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.986); catalogued as rs200058378; called by muse, mutect2
- IFI16 | c.2053A>G p.S685G (on ENST00000295809 / NM_001364867.2; = p.S629G on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as COSV55533341; called by muse, mutect2
- INPP4A | c.2431G>A p.E811K (on ENST00000074304 / NM_001134224.1; = p.E772K on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50785493, COSV99302666; called by muse, mutect2
- IQSEC1 | c.274C>A p.R92S | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs777798451; called by muse, mutect2
- ISYNA1 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 25/439 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs775486515; called by muse, mutect2
- IZUMO3 | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 27/413 reads (7%) | SIFT deleterious (0); catalogued as COSV69048533; called by muse, mutect2
- KSR2 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 18/368 reads (5%) | catalogued as COSV60388681; called by muse, mutect2
- LUC7L | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 26/551 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.921); catalogued as COSV99550907; called by muse, mutect2
- MAGEC1 | c.2368C>A p.L790I | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.036); catalogued as COSV53571076; called by muse, mutect2, varscan2
- NKX3-2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 27/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101219945; called by muse, mutect2
- NTN5 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 45/678 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs983333769, COSV54307093; called by muse, mutect2
- OGDH | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 24/433 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476057637; called by muse, mutect2
- OR4A16 | c.314T>A p.L105H | Missense Mutation (SNP) | VAF 38/540 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as COSV59043856, COSV59044552; called by muse, mutect2
- OR6K2 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 30/538 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs771457648, COSV62743156; called by muse, mutect2
- PCDHB5 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV99168002; called by muse, mutect2
- PCDHB6 | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 34/798 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs782083342, COSV50701157; called by muse, mutect2
- PLEC | c.4969C>T p.R1657C (on ENST00000322810 / NM_201380.4; = p.R1547C on NM_000445.5) | Missense Mutation (SNP) | VAF 83/780 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs782141520; called by muse, mutect2
- PWWP3B | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 105/332 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as COSV61799176; called by muse, mutect2, varscan2
- RYR3 | c.90T>A p.H30Q | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1335066924; called by muse, mutect2
- SEC14L1 | c.2098G>T p.A700S | Missense Mutation (SNP) | VAF 22/365 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.024); catalogued as rs375335873, COSV66720867; called by muse, mutect2
- SLA | c.557G>A p.R186K (on ENST00000338087 / NM_001045556.3; = p.R226K on NM_006748.4) | Missense Mutation (SNP) | VAF 24/526 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1277798136; called by muse, mutect2
- SORCS1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 30/712 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.535); catalogued as rs1262994826, COSV99544071; called by muse, mutect2
- SYNM | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs781799861, COSV60371201; called by muse, mutect2
- TKTL2 | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV99761114; called by muse, mutect2
- TLE4 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs989319452, COSV99511588; called by muse, mutect2
- TNRC6B | c.5452G>T p.A1818S (on ENST00000454349 / NM_001162501.2; = p.A1708S on NM_015088.3) | Missense Mutation (SNP) | VAF 23/370 reads (6%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.987); catalogued as rs755940480; called by muse, mutect2
- TP53 | c.841_842del p.D281Pfs*24 | Frame Shift Del (DEL) | VAF 38/378 reads (10%) | catalogued as rs1567547661; called by pindel, varscan2
- TRPM4 | c.3038C>T p.S1013F | Missense Mutation (SNP) | VAF 27/539 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53260128; called by muse, mutect2
- TSHZ3 | c.2336G>A p.R779H | Missense Mutation (SNP) | VAF 36/574 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as rs546107129, COSV99552029; called by muse, mutect2
- TUBA3C | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 75/641 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.518); catalogued as rs774052893, COSV68027856; called by muse, mutect2, varscan2
- TUBAL3 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 40/446 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.735); catalogued as rs782621046, COSV66814292; called by muse, mutect2
- UPP2 | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 27/370 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs750938118; called by muse, mutect2
- USF3 | c.5189G>A p.R1730H | Missense Mutation (SNP) | VAF 23/328 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs567224928; called by muse, mutect2
- VASH1 | c.434A>G p.K145R | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.086); catalogued as rs938226811; called by muse, mutect2
- WHRN | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 29/570 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1199178665, COSV54332762; called by muse, mutect2
- WIPF2 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 23/452 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV60276591; called by muse, mutect2
- ZFAT | c.3385G>A p.V1129M | Missense Mutation (SNP) | VAF 48/335 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772026910; called by muse, mutect2, varscan2
- ZNF469 | c.8192G>A p.R2731K (on ENST00000437464; = p.R2759K on NM_001367624.2) | Missense Mutation (SNP) | VAF 69/521 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as COSV71258401; called by muse, mutect2, varscan2
- ZNF865 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 43/650 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV73830452; called by muse, mutect2
- AC138647.1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 45/595 reads (8%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- AGMAT | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALMS1 | c.10958A>G p.D3653G | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2
- ARSI | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 24/608 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP6V0E2 | c.153-1G>C p.X51_splice (on ENST00000425642; = p.X100_splice on NM_145230.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 32/411 reads (8%) | called by muse, mutect2
- BRWD3 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf43 | c.227C>A p.P76H (on ENST00000368521 / NM_001297718.2; = p.P42H on NM_015449.4) | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CD44 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2
- CELSR1 | c.7630A>T p.S2544C | Missense Mutation (SNP) | VAF 23/396 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.029); called by muse, mutect2
- CENPI | c.2101C>A p.P701T | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CNKSR2 | c.869T>C p.I290T | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2
- CNTNAP2 | c.805A>C p.S269R | Missense Mutation (SNP) | VAF 32/389 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DACH2 | c.1645C>G p.Q549E | Missense Mutation (SNP) | VAF 97/278 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- DYNC2H1 | c.12554A>T p.Q4185L | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- EIF1 | c.247A>C p.I83L | Missense Mutation (SNP) | VAF 212/477 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- EP400 | c.8483C>T p.T2828M | Missense Mutation (SNP) | VAF 16/596 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GABRB3 | c.746A>G p.Q249R | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HEY2 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 26/656 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); called by muse, mutect2
- HHIPL1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 77/569 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- IGHV4-61 | c.162C>G p.Y54* | Nonsense Mutation (SNP) | VAF 24/592 reads (4%) | called by muse, mutect2
- IQUB | c.1085G>T p.R362I | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); called by muse, mutect2
- JADE2 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 16/541 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- JUP | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 160/2646 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2
- KCNJ5 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 20/542 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LAMA4 | c.469T>A p.C157S | Missense Mutation (SNP) | VAF 10/332 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); called by muse, mutect2
- LRRN2 | c.919G>C p.V307L | Missense Mutation (SNP) | VAF 18/512 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, mutect2
- MARCHF4 | c.1087C>A p.Q363K | Missense Mutation (SNP) | VAF 26/529 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- MDM4 | c.436del p.S146Pfs*29 | Frame Shift Del (DEL) | VAF 35/340 reads (10%) | called by mutect2, pindel, varscan2
- MFAP3 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 23/395 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- MLF1 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 25/370 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.497); called by muse, mutect2
- MOV10 | c.2497T>C p.Y833H | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MPND | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.084); called by muse, mutect2
- MSL1 | c.1280C>A p.S427Y (on ENST00000398532 / NM_001365919.1; = p.S164Y on NM_001012241.2) | Missense Mutation (SNP) | VAF 20/684 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- MUC4 | c.11300C>T p.S3767F | Missense Mutation (SNP) | VAF 29/896 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- NAALADL2 | c.1534-1G>T p.X512_splice | Splice Site (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- NOTCH3 | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- NUDT13 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 32/433 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.058); called by muse, mutect2
- OR14A2 | c.674A>C p.K225T | Missense Mutation (SNP) | VAF 35/471 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- OR14A2 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); called by muse, mutect2
- OR56B4 | c.63_64insATA p.M21_G22insI | In Frame Ins (INS) | VAF 15/370 reads (4%) | called by muse*, mutect2
- OSBPL7 | c.2116C>T p.H706Y | Missense Mutation (SNP) | VAF 19/505 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- PABPC5 | c.513C>A p.N171K | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PCDH10 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 23/522 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PCDH19 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 110/419 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PITPNM3 | c.1240G>T p.V414L | Missense Mutation (SNP) | VAF 51/379 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- POU4F1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 15/526 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, mutect2
- QSOX2 | c.268T>C p.W90R | Missense Mutation (SNP) | VAF 92/472 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- RHOA | c.273_277+29del p.X91_splice | Splice Site (DEL) | VAF 12/173 reads (7%) | called by mutect2, pindel*
- SERPINI2 | c.466A>G p.R156G | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2
- SMAP1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SOHLH1 | c.66C>T p.N22= | Splice Region (SNP) | VAF 20/305 reads (7%) | called by muse, mutect2
- SPAG16 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2
- SYDE2 | c.396C>A p.D132E | Missense Mutation (SNP) | VAF 46/690 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- TDRD9 | c.1723C>T p.L575F | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TENM3 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 16/512 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2
- TMEM200C | c.497A>T p.K166M | Missense Mutation (SNP) | VAF 21/500 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TMEM35A | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNR | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 27/475 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2
- TRIO | c.3344A>C p.E1115A | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- WIPF2 | c.1238A>T p.E413V | Missense Mutation (SNP) | VAF 22/447 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2
- ZNF676 | c.1063A>C p.S355R (on ENST00000650058; = p.S323R on NM_001001411.3) | Missense Mutation (SNP) | VAF 30/768 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- ZNF747 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 28/745 reads (4%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.043); called by muse, mutect2
- ZNF804B | c.3465A>G p.I1155M | Missense Mutation (SNP) | VAF 14/464 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2
- ZXDA | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADORA1 | c.834C>T p.H278= | Silent (SNP) | VAF 37/559 reads (7%) | catalogued as rs748812754; called by muse, mutect2
- COL11A2 | c.219C>T p.R73= | Silent (SNP) | VAF 16/531 reads (3%) | called by muse, mutect2
- CPAMD8 | c.4062C>T p.A1354= (on ENST00000651564; = p.A1307= on NM_015692.5) | Silent (SNP) | VAF 23/466 reads (5%) | called by muse, mutect2
- DOK5 | c.645C>T p.D215= | Silent (SNP) | VAF 36/423 reads (9%) | catalogued as rs375368173; called by muse, mutect2
- EZHIP | c.204C>T p.S68= | Silent (SNP) | VAF 29/330 reads (9%) | called by muse, mutect2
- FAAH | c.852C>T p.A284= | Silent (SNP) | VAF 26/498 reads (5%) | catalogued as COSV99679957; called by muse, mutect2
- FERMT1 | c.1524C>T p.L508= | Silent (SNP) | VAF 73/461 reads (16%) | catalogued as rs1373842038; called by muse, mutect2, varscan2
- FOXD3 | c.1029G>A p.L343= | Silent (SNP) | VAF 38/576 reads (7%) | called by muse, mutect2
- GRM1 | c.255G>A p.T85= | Silent (SNP) | VAF 31/500 reads (6%) | catalogued as rs1562413730, COSV99264368; called by muse, mutect2
- HMGB2 | c.75A>G p.E25= | Silent (SNP) | VAF 18/406 reads (4%) | called by muse, mutect2
- HS3ST3B1 | c.153C>T p.C51= | Silent (SNP) | VAF 20/702 reads (3%) | catalogued as rs1161427928; called by muse, mutect2
- KCNJ12 | c.396G>A p.A132= | Silent (SNP) | VAF 41/996 reads (4%) | catalogued as rs782110956; called by muse, mutect2
- KCNK18 | c.699G>A p.A233= | Silent (SNP) | VAF 30/485 reads (6%) | catalogued as rs772168676; called by muse, mutect2
- KDM5C | c.1848C>T p.N616= | Silent (SNP) | VAF 25/199 reads (13%) | called by muse, mutect2, varscan2
- KIAA1549 | c.2209C>T p.L737= | Silent (SNP) | VAF 24/506 reads (5%) | catalogued as rs1456717627; called by muse, mutect2
- LPIN2 | c.856A>C p.R286= | Silent (SNP) | VAF 15/355 reads (4%) | called by muse, mutect2
- LY6L | c.243C>T p.N81= | Silent (SNP) | VAF 30/564 reads (5%) | catalogued as rs1455333479; called by muse, mutect2
- MAGEL2 | c.1290G>A p.V430= | Silent (SNP) | VAF 34/834 reads (4%) | called by muse, mutect2
- MAN1A1 | c.564C>G p.A188= | Silent (SNP) | VAF 17/544 reads (3%) | catalogued as rs1370464007, COSV63781054; called by muse, mutect2
- MELTF | c.1293G>A p.T431= | Silent (SNP) | VAF 16/438 reads (4%) | catalogued as rs1330182540, COSV99586174; called by muse, mutect2
- OR5M8 | c.60G>T p.R20= | Silent (SNP) | VAF 22/416 reads (5%) | called by muse, mutect2
- PCDHB11 | c.2169A>T p.G723= | Silent (SNP) | VAF 30/690 reads (4%) | catalogued as rs782087145; called by muse, mutect2
- PHRF1 | c.204A>G p.E68= | Silent (SNP) | VAF 20/392 reads (5%) | catalogued as rs1361581927; called by muse, mutect2
- PID1 | c.420A>G p.P140= (on ENST00000354069 / NM_001330156.1; = p.P138= on NM_017933.5) | Silent (SNP) | VAF 40/438 reads (9%) | catalogued as rs762603145; called by muse, mutect2
- PTPRN | c.438C>T p.P146= | Silent (SNP) | VAF 17/463 reads (4%) | called by muse, mutect2
- PUS7L | c.930A>G p.E310= | Silent (SNP) | VAF 43/284 reads (15%) | called by muse, mutect2, varscan2
- RGS20 | c.438G>A p.P146= | Silent (SNP) | VAF 27/670 reads (4%) | called by muse, mutect2
- SCRT1 | c.51G>A p.S17= | Silent (SNP) | VAF 34/342 reads (10%) | called by muse, mutect2
- SLITRK2 | c.288C>T p.N96= | Silent (SNP) | VAF 34/280 reads (12%) | catalogued as rs782326577, COSV59426332; called by muse, mutect2, varscan2
- SVOPL | c.135T>A p.R45= | Silent (SNP) | VAF 20/374 reads (5%) | called by muse, mutect2
- TAS2R16 | c.429T>G p.P143= | Silent (SNP) | VAF 21/461 reads (5%) | called by muse, mutect2
- TRPV3 | c.294C>G p.S98= | Silent (SNP) | VAF 22/470 reads (5%) | called by muse, mutect2
- UNC5B | c.1083C>T p.S361= | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as rs199550912; called by muse, mutect2
- VCPIP1 | c.826C>T p.L276= | Silent (SNP) | VAF 47/538 reads (9%) | called by muse, mutect2
- WASF3 | c.1212G>A p.P404= | Silent (SNP) | VAF 165/532 reads (31%) | catalogued as rs143748235, COSV58972513; called by muse, mutect2, varscan2
- WNK3 | c.1977G>A p.P659= | Silent (SNP) | VAF 27/214 reads (13%) | catalogued as rs377261178; called by muse, mutect2, varscan2
- ZFYVE16 | c.1002T>C p.D334= | Silent (SNP) | VAF 16/356 reads (4%) | called by muse, mutect2
- ANKRD20A8P | n.703T>A | RNA (SNP) | VAF 19/454 reads (4%) | catalogued as rs1402719892; called by muse, mutect2
- PRDM11 | chr11:45226137 C>T | 3'Flank (SNP) | VAF 23/460 reads (5%) | called by muse, mutect2
- RBM44 | c.-98-3149T>C | Intron (SNP) | VAF 8/206 reads (4%) | called by muse, mutect2
- RFESD | c.-44G>T | 5'UTR (SNP) | VAF 11/313 reads (4%) | called by muse, mutect2
- RGS12 | c.1999-16106A>G | Intron (SNP) | VAF 34/315 reads (11%) | called by muse, mutect2, varscan2
- TIGIT | chr3:114293926 T>G | 5'Flank (SNP) | VAF 21/430 reads (5%) | called by muse, mutect2
